Somatic mutation profile of tumor specimen TCGA-BJ-A45G-01A (aliquot TCGA-BJ-A45G-01A-11D-A23U-08) from TCGA case TCGA-BJ-A45G, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 48.8 years (17,831 days).
Specimen TCGA-BJ-A45G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd6fc422-0a3e-49b9-be6b-852c0c06b362.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A45G-10A (Blood Derived Normal), aliquot TCGA-BJ-A45G-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abbd1e80-2057-47bd-b200-c45183222eba

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 56/124 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- B3GNT3 | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57953425; called by muse, mutect2, varscan2
- COG7 | c.1255T>C p.C419R | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100207779; called by muse, mutect2
- IGFBP7 | c.787A>G p.I263V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.987); catalogued as COSV55274256; called by muse, mutect2, varscan2
- KRTAP10-12 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 6/134 reads (4%) | catalogued as COSV100555269; called by muse, mutect2
- NPR1 | c.2405G>A p.R802H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs148747309; called by muse, mutect2, varscan2
- OR4M1 | c.316T>A p.F106I | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV100271485; called by muse, mutect2
- RNASE1 | c.225G>A p.V75= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV61753862; called by muse, mutect2
- TRMT1 | c.1155A>G p.E385= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV55566188; called by muse, mutect2, varscan2
